Somatic mutation profile of tumor specimen MP2PRT-PAPKMH-TMP1-A (aliquot MP2PRT-PAPKMH-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPKMH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (608 days).
Specimen MP2PRT-PAPKMH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fa3d06e-3511-4f81-baad-d98d07c0490b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPKMH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPKMH-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff5794de-f876-467c-8440-bcbbfa14066a

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2AC11 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as COSV60361674; called by muse, mutect2
- HIRA | c.2359G>A p.V787I | Missense Mutation (SNP) | VAF 124/330 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs782075352, COSV54274894; called by muse, mutect2, varscan2
- LIN7A | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 147/425 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs147965628; called by muse, mutect2, varscan2
- MEX3D | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66312132; called by muse, mutect2
- OR1A2 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 26/503 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1567521288; called by muse, mutect2
- ELF1 | c.656_657insCG p.Q219Hfs*42 | Frame Shift Ins (INS) | VAF 32/254 reads (13%) | called by mutect2, pindel*, varscan2
- UBE2Q2 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 202/537 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNRF4 | c.714C>T p.P238= | Silent (SNP) | VAF 200/561 reads (36%) | catalogued as rs376523858, COSV99706679; called by muse, mutect2, varscan2
